Gene-level copy-number profile of tumor specimen TCGA-73-4662-01A from TCGA case TCGA-73-4662, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 65.1 years (23,762 days).
Specimen TCGA-73-4662-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.cdf3df5d-f875-4dcf-96fc-04dd76291c00.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-73-4662-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2a09e2c2-9b13-4a21-9e41-3c7d9886c469

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 971; copy number 2: 19,580; copy number 3: 25,519; copy number 4: 7,982; copy number 5: 3,514; copy number 6: 1,295; copy number 7: 244; copy number 8: 457; copy number 9: 176; copy number 11: 3; copy number 17: 7; copy number 28: 57.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-73-4662-01A-01D-1204-01): tumor purity 0.48, ploidy 3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:235,661,041–235,971,825, 7 genes: LYST, LDHAP2, LYST-AS1, MIR1537, RNU6-968P, AL139161.1, LINC02768.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 944 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:76,041,691–77,219,430, 13 genes, copy number 9 (within-gene range 5–9): AC092813.2, ST6GALNAC3, AC103592.1, AC104458.1, TPI1P1, RNU6-161P, LINC02567, ST6GALNAC5, MIR7156, AL035409.2, AL035409.1, PIGK, AC113935.1.
- chr1:80,451,083–90,533,472, 151 genes, copy number 8 (broad region; genes not listed).
- chr1:164,343,005–172,468,831, 187 genes, copy number 7 (broad region; genes not listed).
- chr1:202,914,880–207,879,115, 163 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr1:209,900,923–211,316,385, 21 genes, copy number 8 (within-gene range 5–8): SYT14, AL022397.1, SERTAD4-AS1, SERTAD4, ST13P19, AL035414.1, HHAT, AL034351.4, RNU5A-8P, AL034351.3, BPNT2P, KCNH1, AC096636.1, AL590132.1, IPO8P1, AC092017.2, AC092017.3, KCNH1-IT1, AC092017.1, PRELID1P5, RCOR3.
- chr1:243,256,034–243,500,091, 1 gene, copy number 8 (within-gene range 5–8): SDCCAG8.
- chr1:243,346,176–248,655,528, 163 genes, copy number 8 (broad region; genes not listed).
- chr1:248,681,322–248,716,755, 3 genes, copy number 8 (within-gene range 2–8): OR14I1, LYPD9P, CR589904.1.
- chr4:14,909,961–23,515,284, 81 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr14:29,952,397–30,297,043, 1 gene, copy number 7 (within-gene range 2–7): AL133372.2.
- chr14:30,370,108–33,804,176, 56 genes, copy number 7: AL079305.1, G2E3-AS1, AL117355.1, SYF2P1, G2E3, SCFD1, UBE2CP1, AL121852.1, RPL12P5, AL049830.2, AL049830.1, COCH, AL049830.3, STRN3, HIGD1AP17, MIR624, AL049830.4, AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1, AL139353.2, DTD2, AL163973.1, GPR33, NUBPL, AL163973.3, AL163973.2, RNU6-602P, RNU6-455P, AL355112.1, LINC02313, AL352984.2, AL352984.1, ARHGAP5-AS1, ARHGAP5, AL161665.1, AL161665.2, RNU6-7, RNU6-8, AL136298.2, KIAA1143P1, AKAP6, AL136298.1, RN7SL660P, MTCO1P2, AL049781.1, NPAS3, AL161851.1, AL161851.2.
- chr14:34,675,891–39,388,513, 104 genes, copy number 8–28 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 971. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
